Somatic mutation profile of tumor specimen TCGA-D3-A2JP-06A (aliquot TCGA-D3-A2JP-06A-11D-A19A-08) from TCGA case TCGA-D3-A2JP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 37.1 years (13,552 days).
Specimen TCGA-D3-A2JP-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f4fdeb3-b030-43c3-a80f-76ea9c88f0af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JP-10A (Blood Derived Normal), aliquot TCGA-D3-A2JP-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b73feca-a457-4d8d-b2ed-e8cf86e4f47b

The open-access MAF lists 296 somatic variants for this specimen: 200 protein-altering or splice-affecting, 94 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 94, Nonsense Mutation 11, Splice Site 3, Frame Shift Del 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- DIS3L2 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as rs199648534, COSV56060410, COSV99806979; ClinVar: pathogenic; called by mutect2, varscan2
- KCNQ5 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 67/131 reads (51%) | catalogued as rs1554201137, COSV59651569; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs769592199, COSV55959234; called by muse, mutect2, varscan2
- AC008397.2 | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53208762; called by muse, mutect2, varscan2
- ACSM2B | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV61658918, COSV61659271; called by muse, mutect2, varscan2
- AFF3 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.642); catalogued as COSV57866286; called by muse, mutect2, varscan2
- AK7 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50878126; called by muse, mutect2, varscan2
- AKAP11 | c.3554T>C p.V1185A | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.085); catalogued as rs1411058096, COSV50299608; called by muse, mutect2, varscan2
- AMPD3 | c.16C>T p.P6S (on ENST00000396553 / NM_001025389.2; = p.P15S on NM_000480.3) | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV67331940; called by muse, mutect2, varscan2
- AP2M1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99490814; called by muse, mutect2, varscan2
- AP2M1 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV99490817; called by muse, mutect2, varscan2
- APOB | c.4171A>G p.M1391V | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV51946504; called by muse, varscan2
- ATAD5 | c.1778C>G p.S593* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV58977445; called by muse, varscan2
- ATP10D | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs1185295382, COSV56711240; called by muse, mutect2, varscan2
- ATP2A2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM990231, COSV58046556; called by muse, mutect2, varscan2
- AURKA | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57169617; called by muse, mutect2, varscan2
- AWAT2 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52144153; called by muse, mutect2, varscan2
- AXIN1 | c.1984C>T p.H662Y | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.642); catalogued as COSV51985411; called by muse, mutect2, varscan2
- BRCA2 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446479156, COSV66459541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CABLES1 | c.1223C>T p.A408V (on ENST00000256925 / NM_001100619.2; = p.A143V on NM_138375.2) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV56936101; called by muse, mutect2, varscan2
- CACNA2D3 | c.3238C>T p.L1080F | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs547203838, COSV55566620; called by muse, mutect2, varscan2
- CCDC61 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV54429870; called by muse, mutect2, varscan2
- CCN4 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV51534301; called by muse, mutect2, varscan2
- CD22 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs776104112, COSV50061342, COSV50061536; called by muse, mutect2, varscan2
- CD2AP | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs879462082, COSV63759167, COSV63762212; called by muse, mutect2, varscan2
- CDR1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV65164583, COSV99054497; called by muse, mutect2, varscan2
- CDRT1 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99887769; called by muse, mutect2, varscan2
- CELSR3 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51031498; called by muse, mutect2, varscan2
- CFAP54 | c.7078G>A p.E2360K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV61574102; called by mutect2, varscan2
- CLPTM1 | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); catalogued as COSV61612646; called by muse, mutect2, varscan2
- CNST | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs773461013, COSV63621466; called by mutect2, varscan2
- COL28A1 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV68083784; called by muse, varscan2
- COL4A4 | c.4117G>A p.D1373N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV61634865; called by muse, varscan2
- CRYBG2 | c.3204G>A p.W1068* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV57488415; called by muse, mutect2, varscan2
- DAB1 | c.880C>G p.P294A (on ENST00000371231; = p.P261A on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs748027334, COSV64690231, COSV64696450; called by muse, mutect2, varscan2
- DGCR2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54220503; called by muse, mutect2, varscan2
- DGKI | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55967522; called by muse, mutect2, varscan2
- DMBT1 | c.3055G>A p.D1019N (on ENST00000338354 / NM_001377530.1; = p.D520N on NM_004406.3) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs773492969, COSV57545842; called by mutect2, varscan2
- DNAH3 | c.3329G>A p.G1110E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54540883, COSV99766181; called by muse, mutect2, varscan2
- DNAH7 | c.6835G>A p.E2279K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV56778275; called by muse, mutect2, varscan2
- DPYS | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755749142, COSV100679404, COSV60911941; called by muse, mutect2, varscan2
- DRD2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.309); catalogued as COSV60755053; called by muse, mutect2, varscan2
- DSE | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.854); catalogued as rs746061603, COSV59066530; called by muse, mutect2, varscan2
- DYSF | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99249571; called by muse, varscan2
- EDNRA | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1156690632, COSV60098560; called by mutect2, varscan2
- EGFR | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51830890; called by muse, varscan2
- ELL | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV99443600; called by mutect2, varscan2
- EPHB2 | c.1718C>T p.A573V (on ENST00000400191 / NM_001309193.2; = p.A574V on NM_004442.7) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV101007285; called by muse, varscan2
- EPHB3 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1475104653, COSV57808185; called by muse, mutect2, varscan2
- ERBB4 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1461443409, COSV53566400; called by muse, varscan2
- ERICH3 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs1401229676, COSV100445191; called by muse, mutect2, varscan2
- F2RL2 | c.752C>G p.T251S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV56971645; called by muse, varscan2
- FAT4 | c.5468C>T p.S1823L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758045956, COSV100628060, COSV58676301; called by mutect2, varscan2
- FBLN1 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as COSV99411125; called by muse, mutect2, varscan2
- FBN3 | c.8371G>A p.G2791R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV53664823; called by muse, mutect2, varscan2
- FBXO15 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54047462; called by muse, mutect2, varscan2
- FBXO31 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV61150439; called by muse, mutect2, varscan2
- FLNB | c.2908G>A p.G970R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199653368, COSV55889964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMNL2 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV56501186; called by mutect2, varscan2
- FNTA | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56489811; called by muse, mutect2, varscan2
- GLI3 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV67893036; called by muse, mutect2, varscan2
- GPRIN1 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as rs1362385963, COSV99991993; called by muse, mutect2, varscan2
- GRIN2B | c.3553G>A p.D1185N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV74206302; called by mutect2, varscan2
- GRIN2B | c.2930A>T p.D977V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV74207134; called by muse, mutect2, varscan2
- HAVCR1 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1202177280, COSV59399962; called by muse, mutect2, varscan2
- HEPHL1 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59894892; called by mutect2, varscan2
- HEPN1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.146); catalogued as COSV53431761; called by muse, mutect2, varscan2
- HERC2 | c.9209C>T p.S3070L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55341787; called by mutect2, varscan2
- HIVEP2 | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs540360531, COSV50036736; called by mutect2, varscan2
- HOMER1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs377464138, COSV56528373; called by mutect2, varscan2
- HOXA2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56067986; called by muse, varscan2
- IL1RL1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs867114006, COSV52119033; called by muse, varscan2
- INHBA | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV54223841; called by muse, mutect2, varscan2
- IQCA1 | c.1152G>A p.W384* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV54514147; called by muse, mutect2, varscan2
- ITPR1 | c.7414G>A p.D2472N (on ENST00000354582; = p.D2417N on NM_002222.7) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV100232559; called by muse, mutect2, varscan2
- JAK1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV61094842; called by muse, mutect2, varscan2
- KCNK13 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV56415741; called by muse, mutect2, varscan2
- KHDRBS2 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55479075; called by muse, mutect2, varscan2
- KIAA1328 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV54461514; called by muse, mutect2, varscan2
- KIF21B | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59763330; called by muse, mutect2, varscan2
- KIF25 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs867244872, COSV63027227; called by muse, mutect2, varscan2
- KIR2DL1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1413328117, COSV52413593; called by muse, mutect2, varscan2
- KLHL4 | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV64139763, COSV64140213; called by muse, varscan2
- KRT39 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.612); catalogued as COSV62917802; called by muse, varscan2
- KRTAP23-1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | PolyPhen benign (0.011); catalogued as rs750836659, COSV100492653; called by mutect2, varscan2
- KRTAP5-3 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); catalogued as rs756119271, COSV68791067; called by muse, mutect2, varscan2
- KSR2 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56679864; called by muse, mutect2, varscan2
- L1TD1 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV63134048; called by muse, mutect2, varscan2
- LARGE2 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV57658256; called by muse, mutect2, varscan2
- LGI2 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV66123674; called by muse, mutect2, varscan2
- LIFR | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV54696723; called by muse, mutect2, varscan2
- LMAN1L | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV100547786; called by mutect2, varscan2
- LRIG3 | c.3329C>T p.P1110L | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.073); catalogued as COSV57867855; called by muse, mutect2, varscan2
- LRRC4C | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53434224; called by mutect2, varscan2
- LRRC7 | c.4262C>T p.S1421F (on ENST00000651989 / NM_001370785.2; = p.S1341F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV50552932; called by muse, mutect2, varscan2
- LRTM1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.077); catalogued as COSV55523265; called by mutect2, varscan2
- MAST1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV52251991; called by mutect2, varscan2
- MCHR2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as rs748678430, COSV56006823; called by mutect2, varscan2
- MDN1 | c.15573G>A p.M5191I | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV65527628; called by muse, mutect2, varscan2
- MINDY2 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as rs759958688, COSV57507942; called by muse, varscan2
- MORC2 | c.470C>T p.P157L (on ENST00000397641 / NM_001303256.3; = p.P95L on NM_014941.3) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53197811, COSV53201357; called by muse, varscan2
- MS4A12 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs889178913, COSV50014281; called by mutect2, varscan2
- MYH15 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56316451; called by muse, mutect2, varscan2
- MYLK | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60608109; called by muse, mutect2, varscan2
- MYOF | c.3184C>T p.H1062Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs868509250, COSV63708569; called by mutect2, varscan2
- NCKAP1 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV62942727; called by muse, mutect2, varscan2
- NDST2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs201159878; called by mutect2, varscan2
- NEBL | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV65804763, COSV65804923; called by muse, mutect2, varscan2
- NLRP11 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV64086711; called by mutect2, varscan2
- NPAS4 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100215205, COSV60651941; called by muse, mutect2, varscan2
- NPHS1 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195878014, COSV62289384; called by muse, mutect2, varscan2
- NSUN7 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV57275536; called by muse, mutect2, varscan2
- OR10A6 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143603778; called by mutect2, varscan2
- OR10G4 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs866856303, COSV57977250; called by muse, mutect2, varscan2
- OR10J3 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs748268654, COSV100171598, COSV59955282; called by muse, mutect2, varscan2
- OR13H1 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.227); catalogued as rs369550150, COSV58548182; called by muse, mutect2, varscan2
- OR1N1 | c.188A>G p.N63S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59196298; called by muse, mutect2, varscan2
- OR4Q3 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100057056, COSV59180444; called by mutect2, varscan2
- OR4S1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as COSV60679689; called by mutect2, varscan2
- OR5P3 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV60429078; called by muse, mutect2, varscan2
- OR8K3 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV57132437, COSV57133525; called by muse, mutect2, varscan2
- OXCT1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52175023; called by muse, varscan2
- PAK5 | c.1891A>C p.I631L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62034424; called by muse, mutect2, varscan2
- PCDHB10 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as rs1554284207, COSV53382142; called by muse, mutect2, varscan2
- PCDHGA8 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV54002963; called by muse, mutect2, varscan2
- PDE1C | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100372838, COSV58523494; called by muse, mutect2, varscan2
- PGM5 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 21/35 reads (60%) | catalogued as rs201509737, COSV67164536; called by muse, mutect2, varscan2
- PLAGL1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV52788353; called by muse, varscan2
- PLEKHM3 | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV66818114; called by mutect2, varscan2
- PLXNB1 | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56489742; called by muse, mutect2, varscan2
- PON1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV55933472; called by muse, varscan2
- PPFIA2 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61046775, COSV61061713; called by mutect2, varscan2
- PRAMEF1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.962); catalogued as COSV60007293; called by muse, varscan2
- PRPF40B | c.67C>T p.P23S (on ENST00000380281; = p.P17S on NM_012272.3) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs768133812, COSV56059525, COSV56061052; called by mutect2, varscan2
- PRR16 | c.188C>T p.S63F (on ENST00000407149 / NM_001300783.2; = p.S40F on NM_016644.2) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1178320083, COSV65403628; called by muse, mutect2, varscan2
- PSG5 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV100743267, COSV61654904; called by muse, mutect2, varscan2
- PSG7 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68445655; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.194C>T p.S65F (on ENST00000421990 / NM_001136042.2; = p.S47F on NM_025267.3) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs372201088; called by muse, mutect2, varscan2
- PTPRD | c.5671G>A p.D1891N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61926952; called by muse, varscan2
- PTPRT | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV62006130; called by muse, mutect2, varscan2
- PWWP2B | c.1625C>T p.S542L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100535597, COSV59452737; called by mutect2, varscan2
- QSOX2 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1282168889, COSV62394906; called by mutect2, varscan2
- RIPOR2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV52426811; called by muse, mutect2, varscan2
- RNF213 | c.7678C>T p.P2560S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100299874, COSV60405433; called by muse, mutect2, varscan2
- RORB | c.1387C>T p.P463S (on ENST00000396204 / NM_001365023.1; = p.P452S on NM_006914.4) | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV65338736; called by muse, mutect2, varscan2
- ROS1 | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV63853396; called by mutect2, varscan2
- SACS | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs762821420, COSV66540239; ClinVar: uncertain significance; called by mutect2, varscan2
- SDK1 | c.4781C>T p.S1594F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67382634; called by muse, mutect2, varscan2
- SIGLEC6 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1224241402, COSV58434515; called by mutect2, varscan2
- SIM1 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as COSV53489222; called by mutect2, varscan2
- SLC24A1 | c.3170C>T p.S1057F | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.355); catalogued as COSV56053383; called by muse, mutect2, varscan2
- SLC25A46 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63506997; called by muse, mutect2
- SLC36A3 | c.1145-1G>A p.X382_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100077774; called by muse, mutect2, varscan2
- SLFN11 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs772949390, COSV57699969; called by muse, mutect2, varscan2
- SOX9 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV99818644; called by muse, mutect2, varscan2
- SPATA13 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV66070572; called by muse, mutect2, varscan2
- SPECC1L | c.1549A>G p.S517G | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58660617; called by muse, mutect2, varscan2
- ST18 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs530224297, COSV52483123; called by mutect2, varscan2
- STAB1 | c.6910G>A p.D2304N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58741040; called by muse, mutect2, varscan2
- STEAP2 | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs775473444, COSV55292862; called by mutect2, varscan2
- STOML2 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53054731; called by muse, mutect2, varscan2
- SUN5 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs746468014, COSV62181084, COSV62181720; called by mutect2, varscan2
- SYT12 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs1218680986, COSV101210977; called by mutect2, varscan2
- TAF4B | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV52308281; called by muse, mutect2, varscan2
- TANC2 | c.5281G>A p.E1761K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.269); catalogued as rs1256980242, COSV67332864, COSV67339103; called by mutect2, varscan2
- TAS1R1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.268); catalogued as COSV100063346; called by mutect2, varscan2
- TAS1R1 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); catalogued as COSV100063348; called by mutect2, varscan2
- TBX20 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.831); catalogued as rs768739120, COSV68785066; called by muse, mutect2, varscan2
- TENM1 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs866209113, COSV64438422; called by mutect2, varscan2
- TEX33 | c.296G>A p.R99Q (on ENST00000381821 / NM_001163857.2; = p.R14Q on NM_178552.4) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV67822621; called by mutect2, varscan2
- TFF1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV52299035; called by muse, mutect2, varscan2
- TGFA | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV54915403; called by muse, mutect2, varscan2
- TLR6 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs375362297; called by mutect2, varscan2
- TM6SF1 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51945758; called by muse, mutect2, varscan2
- TMEM44 | c.934C>T p.L312F (on ENST00000392432 / NM_001166305.2; = p.L265F on NM_138399.5) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56448779; called by muse, mutect2, varscan2
- TMPRSS11B | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100219494, COSV60293525; called by muse, mutect2, varscan2
- TTC21A | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs796655541, COSV57186142, COSV57189454; called by mutect2, varscan2
- TTLL10 | c.1055C>T p.P352L (on ENST00000379289 / NM_001130045.2; = p.P279L on NM_153254.3) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs779469524, COSV64960852; called by mutect2, varscan2
- TTN | c.22008G>A p.W7336* (on ENST00000591111; = p.W6409* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV60140445; called by muse, varscan2
- TTN | c.8497G>A p.E2833K (on ENST00000591111; = p.E2787K on NM_003319.4) | Missense Mutation (SNP) | VAF 51/97 reads (53%) | PolyPhen possibly damaging (0.879); catalogued as COSV60184854; called by muse, mutect2, varscan2
- USP2 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.07); catalogued as rs1565304083, COSV99489877; called by muse, mutect2, varscan2
- USP48 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV57612977; called by muse, mutect2, varscan2
- UTP20 | c.5784G>A p.M1928I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV55382873; called by mutect2, varscan2
- ZMYND15 | c.1145-1G>A p.X382_splice | Splice Site (SNP) | VAF 27/60 reads (45%) | catalogued as COSV52643093; called by muse, mutect2, varscan2
- ZNF182 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1556898530, COSV59358858; called by muse, varscan2
- ZNF208 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs1223569140, COSV68110729; called by mutect2, varscan2
- ZNF229 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as rs187952648, COSV99350007; called by muse, mutect2, varscan2
- ZNF236 | c.4525G>A p.A1509T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV99470934; called by muse, mutect2, varscan2
- ZNF596 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746304311, COSV57654956; called by muse, mutect2, varscan2
- ZNF610 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV58345997; called by muse, varscan2
- ZNF804A | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145158210, COSV56435211, COSV56436532; called by muse, mutect2, varscan2
- ZSWIM2 | c.446T>A p.I149N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54578017; called by muse, mutect2, varscan2
- ZXDC | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV60448018; called by muse, mutect2, varscan2
- AKAP13 | c.8392+2_8392+9del p.X2798_splice (on ENST00000394518 / NM_007200.5; = p.X2802_splice on NM_006738.6) | Splice Site (DEL) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- EFHC1 | c.837del p.H279Qfs*13 | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | called by mutect2, pindel*, varscan2
- IGHV3-74 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PRAMEF19 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- SIM1 | c.1803del p.K601Nfs*41 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- TIMD4 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 89/256 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- AARD | c.414G>A p.L138= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV100991941; called by muse, mutect2, varscan2
- ABHD15 | c.645C>T p.L215= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV56196374; called by mutect2, varscan2
- AC127029.3 | c.648C>T p.F216= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as rs748188371, COSV60111626; called by mutect2, varscan2
- ACAP2 | c.2131T>C p.L711= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV58754455; called by muse, mutect2, varscan2
- ADGRB3 | c.3432C>T p.V1144= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV53255441; called by mutect2, varscan2
- AGBL1 | c.933G>A p.V311= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs566704959, COSV101223969; called by muse, mutect2, varscan2
- ALB | c.1050C>T p.F350= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV55740952; called by muse, mutect2, varscan2
- ARSH | c.609C>T p.L203= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as rs369728930, COSV66963634; called by mutect2, varscan2
- BCAS1 | c.1086C>T p.T362= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV65088385; called by muse, mutect2, varscan2
- C4A | c.2757C>T p.F919= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs529197965, COSV71178556; called by mutect2, varscan2
- CAPN10 | c.444C>T p.L148= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs769197972; called by mutect2, varscan2
- CASR | c.1212C>T p.V404= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs967661303, COSV56135617; called by mutect2, varscan2
- CDRT1 | c.630C>T p.A210= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99887764; called by muse, mutect2, varscan2
- CNTN4 | c.570G>A p.G190= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1331841920, COSV61875990; called by muse, varscan2
- COL4A6 | c.3030C>T p.I1010= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1234073336, COSV57873779; called by mutect2, varscan2
- CPA3 | c.1128C>T p.A376= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV56046654; called by muse, mutect2, varscan2
- CYB561D1 | c.654C>T p.S218= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV60205681; called by muse, mutect2, varscan2
- CYP4F12 | c.1512G>A p.L504= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1336840844, COSV61175606; called by mutect2, varscan2
- DDX58 | c.210C>T p.F70= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as COSV65883269; called by muse, mutect2, varscan2
- DNAH5 | c.9678G>A p.A3226= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as rs547729937, COSV54207337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPB41L1 | c.819C>T p.F273= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52442147; called by muse, mutect2, varscan2
- EPHB2 | c.1719T>C p.A573= (on ENST00000400191 / NM_001309193.2; = p.A574= on NM_004442.7) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101007286; called by muse, mutect2, varscan2
- FAM170A | c.933G>A p.R311= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV58926544; called by muse, mutect2, varscan2
- FBLN1 | c.732G>A p.R244= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs1569243453, COSV53045269, COSV99411120; called by muse, mutect2, varscan2
- FCHO1 | c.474G>A p.Q158= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV53184307; called by muse, mutect2, varscan2
- FFAR4 | c.642G>A p.L214= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV65179430; called by mutect2, varscan2
- GAREM1 | c.918C>T p.F306= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV52514171; called by mutect2, varscan2
- GLI3 | c.3888C>T p.G1296= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101229971; called by muse, mutect2, varscan2
- GLRA1 | c.408C>T p.F136= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV51007438, COSV51008702; called by muse, varscan2
- GPRIN1 | c.1803C>T p.I601= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV99991172; called by muse, mutect2, varscan2
- HOXA2 | c.723G>A p.G241= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99761351; called by muse, varscan2
- IQSEC2 | c.3075C>T p.F1025= (on ENST00000642864 / NM_001111125.3; = p.F820= on NM_015075.2) | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as COSV64727322; called by muse, mutect2, varscan2
- ITPR1 | c.7413A>G p.V2471= (on ENST00000354582; = p.V2416= on NM_002222.7) | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100232558; called by muse, mutect2, varscan2
- JADE3 | c.1515G>A p.Q505= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs1556373375, COSV54471464; called by muse, mutect2
- KALRN | c.8640C>T p.F2880= (on ENST00000360013 / NM_001024660.4; = p.F1183= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV52261968, COSV99362508; called by muse, mutect2, varscan2
- KAT6B | c.3564C>T p.V1188= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99768729; called by muse, mutect2, varscan2
- KAT6B | c.3565C>T p.L1189= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99768732; called by muse, mutect2, varscan2
- KCNJ16 | c.456C>T p.L152= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV52256223; called by mutect2, varscan2
- LMOD2 | c.852G>A p.G284= | Silent (SNP) | VAF 46/62 reads (74%) | catalogued as COSV71755776; called by muse, mutect2, varscan2
- LMTK3 | c.474C>T p.P158= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs999224904, COSV99540982; called by muse, mutect2, varscan2
- LPP | c.417T>C p.P139= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV57107228; called by muse, mutect2, varscan2
- LVRN | c.766C>T p.L256= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV63497984; called by muse, mutect2, varscan2
- MAGEB16 | c.726C>T p.I242= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV67873599; called by muse, mutect2, varscan2
- MARCO | c.1476G>A p.E492= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV59056952, COSV59059274; called by muse, mutect2
- MAST2 | c.5085G>A p.K1695= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV53110103; called by muse, mutect2, varscan2
- MCM7 | c.129G>A p.R43= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV57998228; called by muse, mutect2, varscan2
- MICAL2 | c.4014G>A p.R1338= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs1342867252, COSV56287876; called by muse, mutect2, varscan2
- MUC16 | c.6501G>A p.P2167= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs768752085, COSV67482462; called by muse, mutect2, varscan2
- MYO1G | c.2208C>T p.I736= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV51856302; called by muse, mutect2, varscan2
- MYO3B | c.3519C>T p.S1173= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58712477; called by muse, mutect2, varscan2
- NLRP5 | c.1626G>A p.R542= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV66764567; called by muse, mutect2, varscan2
- OR1F1 | c.597C>T p.I199= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV58961092; called by muse, mutect2, varscan2
- OR4M1 | c.405C>T p.I135= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV60059517, COSV60061611; called by mutect2, varscan2
- OR4N5 | c.699G>A p.K233= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV100374217, COSV61321055; called by muse, mutect2, varscan2
- OR5B12 | c.267C>T p.F89= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs867169291, COSV100222406, COSV56905096; called by mutect2, varscan2
- OTOF | c.5637C>T p.S1879= (on ENST00000272371 / NM_194248.3; = p.S1112= on NM_004802.4) | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99718497; called by muse, mutect2, varscan2
- OTOL1 | c.1098C>T p.L366= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs1560143863, COSV60007886; called by muse, mutect2, varscan2
- PES1 | c.1563G>A p.K521= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV58829370; called by muse, mutect2, varscan2
- PLCZ1 | c.1341G>A p.G447= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV56849281; called by muse, mutect2, varscan2
- PPP2R5B | c.1101C>T p.S367= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV51212066; called by muse, mutect2, varscan2
- PRUNE2 | c.9106C>T p.L3036= | Silent (SNP) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- PTPRN | c.1368C>A p.P456= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV55350857, COSV55353239; called by mutect2, varscan2
- RASAL3 | c.777C>T p.P259= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV59141053; called by muse, mutect2, varscan2
- RIMS1 | c.189G>A p.K63= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV53454216, COSV53474170; called by mutect2, varscan2
- SCN7A | c.2793A>G p.V931= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1218475884, COSV69273714; called by muse, mutect2, varscan2
- SERPINB3 | c.1113C>T p.F371= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1467070831, COSV52193195, COSV52193267; called by muse, mutect2, varscan2
- SERPINB8 | c.750C>T p.F250= | Silent (SNP) | VAF 78/171 reads (46%) | catalogued as rs974460908, COSV54640139, COSV54640341; called by muse, mutect2, varscan2
- SH3BP4 | c.1587C>T p.F529= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs765228030, COSV60642190; called by mutect2, varscan2
- SLAMF1 | c.573C>T p.S191= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV52501084; called by muse, mutect2, varscan2
- SLC18A2 | c.1161G>A p.P387= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs779480733, COSV53689703; called by mutect2, varscan2
- SLC22A6 | c.501G>A p.L167= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV64560792; called by mutect2, varscan2
- SLC6A6 | c.45G>A p.K15= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV62651777; called by muse, mutect2, varscan2
- SUZ12 | c.2166G>A p.L722= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV59502307; called by muse, mutect2, varscan2
- SYT12 | c.279C>T p.S93= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV101210975; called by muse, mutect2, varscan2
- TENM4 | c.4515C>T p.L1505= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs372767827; called by muse, mutect2, varscan2
- TGIF2 | c.187C>T p.L63= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV65836272; called by muse, mutect2, varscan2
- THY1 | c.453C>T p.S151= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV52454976; called by muse, mutect2, varscan2
- TMEM130 | c.795C>T p.F265= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV59559757; called by muse, mutect2, varscan2
- TMEM267 | c.393T>C p.T131= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV67993012; called by muse, mutect2, varscan2
- TNFRSF11B | c.747G>A p.Q249= | Silent (SNP) | VAF 99/185 reads (54%) | catalogued as COSV52073121; called by muse, mutect2, varscan2
- TNRC6B | c.3702C>T p.S1234= (on ENST00000454349 / NM_001162501.2; = p.S1124= on NM_015088.3) | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV57304175; called by muse, varscan2
- TPCN1 | c.1611C>T p.V537= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1326525973, COSV59238248; called by muse, mutect2, varscan2
- TRAV21 | c.156C>T p.L52= | Silent (SNP) | VAF 16/23 reads (70%) | called by muse, mutect2, varscan2
- TRAV26-1 | c.258G>A p.K86= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs369822978; called by muse, mutect2, varscan2
- TRAV8-4 | c.240C>T p.N80= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs189913064; called by muse, mutect2, varscan2
- TTLL9 | c.261C>T p.F87= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs746084067, COSV60595159; called by mutect2, varscan2
- WFDC10B | c.117C>A p.P39= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV57914559; called by mutect2, varscan2
- XIRP2 | c.9450C>T p.F3150= (on ENST00000628543; = p.F3325= on NM_152381.6) | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1553505593, COSV54686043, COSV54714181; called by mutect2, varscan2
- ZFP41 | c.291G>A p.K97= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs1444248545, COSV100414722, COSV58087950; called by muse, mutect2, varscan2
- ZNF236 | c.4524G>A p.Q1508= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99470930; called by muse, mutect2, varscan2
- ZNF451 | c.1413C>T p.T471= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV62599138; called by muse, mutect2, varscan2
- ZNF496 | c.1164C>T p.S388= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV54175855; called by muse, mutect2, varscan2
- ZNF518B | c.2268C>T p.T756= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV58723934; called by muse, mutect2, varscan2
- ZNF76 | c.615C>T p.A205= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV57591868; called by muse, mutect2, varscan2
- MIR495 | n.34C>T | RNA (SNP) | VAF 7/13 reads (54%) | catalogued as rs1387305475; called by mutect2, varscan2
- XIST | n.8777G>A | RNA (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
